Surgical pathology report (de-identified scan), TCGA case TCGA-55-6983, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6983-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Requested by: [REDACTED]

Patient [REDACTED]
MRN [REDACTED]
Date of Service [REDACTED]
Performing Facility [REDACTED]
Ordering Provider [REDACTED]
Result Provider [REDACTED]
Report Name :Surgical Report

==== MICROSCOPIC DESCRIPTION: =====

A/APC. One slide is examined. Seen are sections of one benign lymph node. There is no evidence of metastatic carcinoma.
B/BPC. One slide is examined. Seen are sections of two benign lymph nodes. There is no evidence of metastatic carcinoma.
C/CPC. Two slides are examined. Seen are sections of a lymph node. A focus of metastatic carcinoma is seen in slide C/CPC-1.
D. One slide is examined. Seen are sections of six lymph nodes. Metastatic carcinoma is seen in two nodes.
E/EPC. Fourteen slides, including two EPC slides, are examined. Seen are sections of lung demonstrating an infiltrating mucinous carcinoma. Abundant extravasated mucin is present. Carcinoma extends to the visceral pleura, but does not penetrate through it. Small vessel (lymphatic space) invasion is present. Large vessel (venous) invasion is not evident. Also seen within the non-neoplastic lung tissue are multifocal nodular areas of inflammation and fibroblastic proliferation centered around bronchioles. These foci are associated with prominent bronchiolar destruction. The bronchioles and vascular resection margins are negative for tumor.
ADDENDUM [REDACTED]: The actual slides examined at the time of frozen section are reviewed. Slides A/APC, B/BPC and C/CPC, which represent smears of lymph nodes examined at the time of frozen section, show no evidence of metastatic tumor. Slides E/EPC show mucinous carcinoma of the lung with negative bronchial resection margin.

==== SPECIAL STAINS: =====

A panel of immunostains including CK7, CK20, and TTF-1 were performed on paraffin block E3. The neoplastic cells show positive staining for CK7 and TTF-1. CK20 stain is negative. This staining profile is compatible with primary lung carcinoma.
The control slides are reviewed and found to stain appropriately.

==== FINAL DIAGNOSIS: =====

A/APC. INFERIOR PULMONARY LIGAMENT, LYMPH NODE, EXCISION: ONE BENIGN LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1)
B/BPC. SUBCARINAL LYMPH NODE, EXCISION: TWO BENIGN LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/2)
CPC. HILAR LYMPH NODE, EXCISION: NEGATIVE FOR CARCINOMA ON SMEAR
C. HILAR LYMPH NODE, EXCISION: METASTATIC CARCINOMA IN ONE LYMPH NODE (1/1); PLEASE SEE COMMENT
D. PROXIMAL BRONCHIAL LYMPH NODE, EXCISION: METASTATIC CARCINOMA IN TWO OUT OF SIX LYMPH NODES (2/6)
E/EPC. LEFT LOWER LOBE OF LUNG, LOBECTOMY:

[page 2 of 2]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name

Presented by: [REDACTED]

1. HISTOLOGIC TYPE: MUCINOUS ADENOCARCINOMA
2. HISTOLOGIC GRADE: WELL TO MODERATELY DIFFERENTIATED
3. PATHOLOGIC STAGING: pT2 (TUMOR MEASURES 8.5 CM IN MAXIMAL DIMENSION)
4. REGIONAL LYMPH NODE: METASTATIC CARCINOMA PRESENT IN ONE OUT OF THREE HILAR LYMPH NODES; PLEASE ALSO REFER TO SPECIMENS A/APC, B/BPC & C/CPC & D T2
5. DISTANT METASTASIS: NOT ASSESSED
6. MARGINS: BRONCHIAL AND VASCULAR RESECTION MARGINS ARE NEGATIVE N1
FOR TUMOR
7. DIRECT EXTENSION OF TUMOR: NOT ASSESSED
8. VENOUS (LARGE) VESSEL INVASION: NOT IDENTIFIED
9. ARTERIOLE (LARGE) VESSEL INVASION: NOT IDENTIFIED
10. LYMPHATIC (SMALL) VESSEL INVASION: PRESENT
11. ADDITIONAL PATHOLOGIC FINDINGS:
- MULTIFOCAL NODULAR AREAS OF BRONCHIOLAR PNEUMONITIS WITH A BOOP LIKE PATTERN

COMMENT: The permanent section slides on specimen C show metastatic carcinoma within one lymph node. The corresponding smear examined at the time of frozen sections shows no evidence of tumor.

A-MALIGNANT

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1f0d88ef-0a29-4090-a5ef-8b76b863ff6f (TCGA-55-6983.5428A18C-8DB6-4DBC-BEC0-B55658F3302B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).